Somatic mutation profile of tumor specimen MMRF_1746_1_BM_CD138pos (aliquot MMRF_1746_1_BM_CD138pos_T2_KBS5U_K11931) from MMRF case MMRF_1746, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.6 years (18,862 days).
Specimen MMRF_1746_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa9c71b4-5f35-4877-a449-f562106ebebd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1746_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1746_1_PB_Whole_C7_KBS5U_K11894; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79741ee3-c5ce-4cac-b927-c95fbd34888d

The open-access MAF lists 117 somatic variants for this specimen: 48 protein-altering or splice-affecting, 9 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 39, Missense Mutation 37, Silent 9, 5'UTR 7, Intron 6, 3'Flank 5, Frame Shift Del 5, Splice Site 2, Nonsense Mutation 2, In Frame Del 2, RNA 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX2 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs777307009; called by muse, mutect2, varscan2
- CHD5 | c.3406C>T p.R1136C | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52417296; called by muse, mutect2, varscan2
- COLGALT1 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs572639404; called by muse, mutect2, varscan2
- GRIN2A | c.1529G>A p.G510D | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100410494, COSV58054160; called by muse, mutect2, varscan2
- GRM1 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1562414099, COSV51123819, COSV51138034; called by muse, mutect2, varscan2
- IGHJ6 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 34/56 reads (61%) | PolyPhen benign (0.069); catalogued as rs368585758; called by muse, varscan2
- IGHV2-70 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.433); catalogued as rs372630587; called by muse, varscan2
- IGHV2-70D | c.218A>C p.D73A | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.059); catalogued as rs1191956174; called by muse, varscan2
- IL1RN | c.77G>A p.R26Q (on ENST00000409930 / NM_173842.3; = p.R8Q on NM_000577.5) | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs758363942, COSV52080666; called by muse, mutect2
- KCNH5 | c.2828C>T p.S943L | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs761523326, COSV59765241; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1549 | c.4018C>G p.Q1340E | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs978748287; called by muse, mutect2
- KNDC1 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs777918546; called by muse, mutect2, varscan2
- LRRTM1 | c.1260G>T p.E420D | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54438825; called by muse, mutect2
- MEIS1 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.07); catalogued as COSV55483316; called by muse, mutect2, varscan2
- MYH7 | c.5774G>A p.R1925H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs752553589, COSV62520138; ClinVar: uncertain significance; called by mutect2, varscan2
- PCDHB16 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 103/252 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53364295; called by muse, mutect2, varscan2
- PCDHGA4 | c.1546del p.A516Pfs*47 | Frame Shift Del (DEL) | VAF 90/289 reads (31%) | catalogued as COSV53905174; called by mutect2, pindel, varscan2
- REV1 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV51490269; called by muse, mutect2, varscan2
- SEC23B | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV52723086; called by muse, mutect2, varscan2
- TMEM121 | c.625A>T p.I209L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs373008663; called by muse, mutect2, varscan2
- TTN | c.21677C>T p.P7226L (on ENST00000591111; = p.P6299L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/265 reads (36%) | PolyPhen benign (0.19); catalogued as rs560272834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBTFL1 | c.444del p.K148Nfs*27 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | catalogued as COSV73297853; called by mutect2, pindel
- ACTA1 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- ANKRD40 | c.47A>T p.E16V | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- C6orf47 | c.76T>A p.Y26N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); called by muse, mutect2
- CDCP2 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.934); called by muse, mutect2
- FARP2 | c.2213A>C p.E738A | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FILIP1L | c.2488G>T p.E830* (on ENST00000354552 / NM_182909.3; = p.E590* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/214 reads (12%) | called by muse, mutect2, varscan2
- GCM2 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- GFRA2 | c.1045+1del p.X349_splice | Splice Site (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- GPR149 | c.713T>A p.I238N | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- H4C2 | c.137_147del p.R46Lfs*4 | Frame Shift Del (DEL) | VAF 58/174 reads (33%) | called by mutect2, pindel, varscan2
- H4C9 | c.301_306del p.F101_G102del | In Frame Del (DEL) | VAF 31/101 reads (31%) | called by mutect2, pindel, varscan2
- IER2 | c.40T>C p.S14P | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IFI44 | c.787T>G p.C263G | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- IGHV2-70 | c.117_139del p.C41Qfs*3 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | called by pindel, varscan2
- IGHV2-70D | c.329_338delinsCT p.D110Afs*? | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by pindel, varscan2*
- ITGB3BP | c.255-1G>A p.X85_splice | Splice Site (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- KIF16B | c.1559C>G p.S520C | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- MORF4L1 | c.538G>A p.D180N (on ENST00000331268 / NM_206839.2; = p.D141N on NM_006791.4) | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); called by muse, mutect2
- ODAM | c.395_397del p.S132del | In Frame Del (DEL) | VAF 33/159 reads (21%) | called by mutect2, pindel, varscan2
- PLEKHG2 | c.3587C>T p.P1196L | Missense Mutation (SNP) | VAF 25/298 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.521); called by muse, mutect2
- RFNG | c.562G>C p.G188R | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- SCN1A | c.5390C>G p.A1797G (on ENST00000303395 / NM_001202435.3; = p.A1786G on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- SPEN | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIML1 | c.849A>T p.K283N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- WDR46 | c.1397A>G p.H466R | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF253 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- BCL11B | c.1443C>T p.A481= (on ENST00000357195 / NM_001282237.2; = p.A410= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs932315850, COSV61734471; called by muse, mutect2
- JUN | c.147G>C p.L49= | Silent (SNP) | VAF 20/199 reads (10%) | called by muse, mutect2, varscan2
- KIAA1217 | c.3351C>T p.T1117= | Silent (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- KIF16B | c.1560C>T p.S520= | Silent (SNP) | VAF 10/115 reads (9%) | called by muse, mutect2
- MYH9 | c.4974C>T p.R1658= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as rs776733292, COSV53385907; called by muse, mutect2, varscan2
- MYO7B | c.3507C>A p.R1169= | Silent (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- PADI1 | c.1734C>T p.Y578= | Silent (SNP) | VAF 8/206 reads (4%) | catalogued as rs747045477, COSV64938739; called by muse, mutect2
- PARP2 | c.111G>A p.K37= | Silent (SNP) | VAF 6/129 reads (5%) | called by muse, mutect2
- PHOSPHO2 | c.243C>G p.L81= | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as COSV55869356; called by muse, mutect2
- AC094103.1 | n.408G>C | RNA (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- ACTBL2 | c.-25C>T | 5'UTR (SNP) | VAF 105/353 reads (30%) | catalogued as rs759563978; called by muse, mutect2, varscan2
- ADCY3 | c.-380G>T | 5'UTR (SNP) | VAF 59/185 reads (32%) | called by muse, mutect2, varscan2
- ALS2 | c.2351+155G>C | Intron (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2
- ANAPC2 | c.*137G>C | 3'UTR (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- BCL3 | c.*34G>A | 3'UTR (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- CHL1 | chr3:407077 T>C | 3'Flank (SNP) | VAF 44/119 reads (37%) | called by muse, mutect2, varscan2
- CHML | c.*2692G>A | 3'UTR (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- CMBL | c.*232C>G | 3'UTR (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
- CNIH2 | c.456-68G>A | Intron (SNP) | VAF 50/157 reads (32%) | called by muse, mutect2, varscan2
- CNOT6L | c.*4080G>C | 3'UTR (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2, varscan2
- CNOT6L | c.*2965G>A | 3'UTR (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- CSMD1 | chr8:2936563 C>A | 3'Flank (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- CTSD | c.*206G>C | 3'UTR (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- DARS1 | c.-19T>C | 5'UTR (SNP) | VAF 48/157 reads (31%) | called by muse, mutect2, varscan2
- ERAP1 | chr5:96771824 G>T | 3'Flank (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- ERMP1 | c.*1476G>A | 3'UTR (SNP) | VAF 15/162 reads (9%) | called by muse, mutect2
- GALNT10 | c.*3638T>A | 3'UTR (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- GALNT18 | c.*64C>T | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- GNB5 | c.*548C>A | 3'UTR (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- GNS | c.*983G>A | 3'UTR (SNP) | VAF 6/96 reads (6%) | catalogued as rs1006147463; called by muse, mutect2
- GRAP2 | c.-14-34G>A | Intron (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- GRIA4 | c.*300C>T | 3'UTR (SNP) | VAF 28/92 reads (30%) | called by muse, mutect2, varscan2
- HOXB2 | c.*360T>C | 3'UTR (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2
- IGLON5 | c.*124G>A | 3'UTR (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- IYD | c.*5840C>T | 3'UTR (SNP) | VAF 8/46 reads (17%) | catalogued as rs1398858948; called by muse, mutect2, varscan2
- LATS2 | c.*1617G>A | 3'UTR (SNP) | VAF 37/156 reads (24%) | called by muse, mutect2, varscan2
- MAN1A2 | c.-646G>A | 5'UTR (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- METTL2B | c.*4237G>A | 3'UTR (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- NAT8 | c.*57T>C | 3'UTR (SNP) | VAF 73/210 reads (35%) | called by muse, mutect2, varscan2
- NEUROD1 | c.*693A>G | 3'UTR (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- NEXMIF | c.*1915G>C | 3'UTR (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- NR2F2-AS1 | n.1027T>A | RNA (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- PKP4 | chr2:158682749 C>A | 3'Flank (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- PLA2R1 | c.*2793A>G | 3'UTR (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- PPP2R1B | chr11:111737549 T>G | 3'Flank (SNP) | VAF 10/205 reads (5%) | called by muse, mutect2
- PRKN | c.*2626G>C | 3'UTR (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- PRPH2 | c.-239A>G | 5'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- RFLNB | c.*3101G>A | 3'UTR (SNP) | VAF 21/92 reads (23%) | catalogued as rs1191714213, COSV61239765; called by muse, mutect2, varscan2
- RNF168 | c.-347G>A | 5'UTR (SNP) | VAF 49/159 reads (31%) | catalogued as rs1300480984; called by muse, mutect2, varscan2
- SAA4 | chr11:18240213 G>T | 5'Flank (SNP) | VAF 27/288 reads (9%) | called by muse, mutect2
- SCN3B | c.*890G>A | 3'UTR (SNP) | VAF 13/40 reads (33%) | catalogued as rs985221246; called by muse, mutect2, varscan2
- SEC24A | c.*1084C>G | 3'UTR (SNP) | VAF 5/107 reads (5%) | called by muse, mutect2
- SETD7 | c.*177del | 3'UTR (DEL) | VAF 6/52 reads (12%) | catalogued as rs1309376470; called by mutect2, pindel, varscan2
- SHB | c.-195dup | 5'UTR (INS) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- SLCO1B3 | c.*20G>C | 3'UTR (SNP) | VAF 21/242 reads (9%) | called by muse, mutect2
- SNTN | c.*1080A>G | 3'UTR (SNP) | VAF 35/105 reads (33%) | catalogued as rs1485704345; called by muse, mutect2, varscan2
- SNX10 | c.*807C>G | 3'UTR (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- STK36 | c.2586+181C>T | Intron (SNP) | VAF 6/47 reads (13%) | catalogued as rs1005216758; called by muse, mutect2, varscan2
- TMCO3 | c.*27G>C | 3'UTR (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2, varscan2
- TMEM97 | c.*1534C>T | 3'UTR (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- TNFSF15 | c.301+351dup | Intron (INS) | VAF 14/36 reads (39%) | catalogued as rs1466519815; called by mutect2, varscan2
- TNRC6B | c.*9270C>T | 3'UTR (SNP) | VAF 12/39 reads (31%) | catalogued as rs1007924695; called by muse, mutect2, varscan2
- TPBG | c.*684_*685insT | 3'UTR (INS) | VAF 19/94 reads (20%) | catalogued as rs1562155613; called by mutect2, pindel, varscan2
- TRIM58 | c.*62T>C | 3'UTR (SNP) | VAF 46/344 reads (13%) | called by muse, mutect2, varscan2
- TRPS1 | c.-3+586G>A | Intron (SNP) | VAF 11/111 reads (10%) | catalogued as rs1026090382; called by muse, mutect2, varscan2
- WWC2 | c.*2244A>G | 3'UTR (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- XPNPEP3 | c.*5969dup | 3'UTR (INS) | VAF 19/69 reads (28%) | called by mutect2, pindel, varscan2
- YWHAB | c.*52T>C | 3'UTR (SNP) | VAF 62/158 reads (39%) | catalogued as rs375543853; called by muse, mutect2, varscan2
- ZNF75A | c.*541C>T | 3'UTR (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
